CCDI case PBBZBY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d601dda7-2aa0-4c62-a753-895b903b7ff6

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 2.9 years (1,064 days).

Biospecimens (3 samples)
- Sample 0DLHO9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLHOJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLHP0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
